Surgical pathology report (de-identified scan), TCGA case TCGA-BS-A0U7, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii, specimen TCGA-BS-A0U7-01A (Primary Tumor).

[page 1 of 2]
Endocrine Discrepancy		
SPAA Discrepancy		
For Malignancy History		
Asynchronous Primary Noted		

1CD-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: Endometrium C54.1
hw 5/1/11

Surgical Pathology Report

Patient Name: [Redacted] Client: [Redacted]
Med. Rec. #: [Redacted] Location: [Redacted]
DOB: [Redacted]
Gender: F
Physician(s): [Redacted]
cc: [Redacted]

Accession #
Taken:
Received:
Reported:

History/Clinical Dx: Endometrial cancer
Postoperative Dx: Pending pathology examination

Specimen(s) Received:

- A: Right tube and ovary
- B: Left tube and ovary
- C: Uterus, cervix
- D: Left pelvic lymph node
- E: Left aortic lymph node
- F: Right pelvic lymph node
- G: Right aortic lymph node

Handwritten: T1c grade 2

DIAGNOSIS:

- | | |
|--------------------------|--|
| A. Right tube and ovary: | Tube and ovary with no evidence of tumor |
| B. Left tube and ovary: | Tube and ovary with no evidence of tumor |
| C. Uterus, cervix: | ENDOMETRIAL ADENOCARCINOMA |

Tumor Information:

Operative procedure:	Radical hysterectomy
Histologic type:	Endometrioid
Histologic grade(FIGO):	Grade 2
Nuclear grade:	2
Extent of invasion:	> 50% (1.4 cm of invasion; myometrial thickness of 2.7 cm)
Lympho/vascular invasion:	Probable
Serosa:	Free of tumor
Parametrium:	Free of tumor
Cervical involvement:	Absent
Right adnexa:	Free of tumor
Left adnexa:	Free of tumor
Other findings:	Leiomyomata, intramural
Staging:	T1c, N0

- | | |
|----------------------------|---|
| D. Left pelvic lymph node: | Six lymph nodes negative for metastasis (0/6) |
| E. Left aortic lymph node: | Seven lymph nodes negative for metastasis (0/7) |

Regulatory Statement: The following statement may be applicable to some of the reagents/antibodies used in developing the above report. This test was developed and its performance characteristics determined by [Redacted] It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 2]
Surgical Pathology Report

- F. Right pelvic lymph node: Seven lymph nodes negative for metastasis (0/7)
- G. Right aortic lymph node: Seven lymph nodes negative for metastasis (0/7)

Gross Description

- A. Submitted as "right tube and ovary" is an ovary with attached fallopian tube. The ovary measures 2.2 x 1.0 x 0.8 cm in greatest dimensions and is grossly unremarkable. The tube measures 4.0 cm in length and is also grossly unremarkable. Representative sections submitted in two cassettes.
- B. Submitted as "left tube and ovary" is an ovary measuring 2.2 x 1.5 x 0.7 cm in greatest dimension. Serial sectioning is grossly unremarkable. The attached fallopian tube measures 4.5 cm in length and is grossly unremarkable. Representative sections submitted in two cassettes.
- C. Submitted as "uterus and cervix" is a uterus with attached cervix weighing 83 gm and measuring 7.3 x 3.5 x 4.2 cm in greatest dimension. The specimen has been opened along the anterior aspect. The ectocervical mucosa is smooth. The endocervical canal is grossly unremarkable. The endometrial cavity is lined by markedly shaggy mucosa involving most of the mid and superior portion. The mucosa is friable and raised above the surface 0.7 cm. This area of apparent tumor measures 3.4 x 3.0 x 0.7 cm. Serial sectioning shows apparent early myometrial invasion with grossly approximately 2.0 mm of invasion into the myometrium which measures 2.7 cm in thickness. The serosal surface is smooth. Also within the myometrium are several smaller well circumscribed nodules, each with a whorled cut surface. They measure up to 0.8 cm.

KEY TO CASSETTES

- C1-2 - Cervix
C3 - Upper endocervical canal
C4-8 - Sections of tumor and underlying myometrium
C9 - Right parametrium
C10 - Left parametrium

- D. Submitted as "left pelvic lymph nodes" are several fragments of fibrofatty tissue containing multiple nodes. Individual nodes are submitted in cassettes D1 and D2.
- E. Submitted as "left aortic node" is a fragment of fibrofatty tissue weighing 2 gm. Lymph node tissue is removed and submitted intact in cassettes E1 and E2.
- F. Submitted as "right pelvic nodes" are two fragments of fibrofatty tissue containing multiple lymph nodes.

KEY TO CASSETTES

- F1-2 - Individual nodes
F3 - Single bisected node

- G. Submitted as "right aortic node" is a single fragment of fibrofatty tissue weighing 2 gm. Several lymph nodes are present. The entire specimen is submitted in two cassettes.

Microscopic Description

The microscopic findings support the above diagnosis.

Source: NCI Genomic Data Commons file 572c0c33-b9d0-4069-a56b-5a4d68032bf1 (TCGA-BS-A0U7.BE83021F-D4D5-4ECA-8484-8A37B2FE67C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).